Somatic mutation profile of tumor specimen TCGA-AO-A03V-01A (aliquot TCGA-AO-A03V-01A-11D-A10Y-09) from TCGA case TCGA-AO-A03V, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 41.8 years (15,284 days).
Specimen TCGA-AO-A03V-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9fb76489-453d-499f-88fd-446283557433.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AO-A03V-10A (Blood Derived Normal), aliquot TCGA-AO-A03V-10A-01D-A110-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e20fa4e2-7404-453f-b297-6ad7229cd527

The open-access MAF lists 54 somatic variants for this specimen: 46 protein-altering or splice-affecting, 8 silent.
By variant classification: Missense Mutation 41, Silent 8, Splice Site 1, Nonsense Mutation 1, In Frame Del 1, Frame Shift Del 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- C19orf12 | c.32C>T p.T11M | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.01); catalogued as rs397514477, CM118377, COSV60365136; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.734G>A p.G245D | Missense Mutation (SNP) | VAF 34/48 reads (71%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121912656, CM010464, CM900209, COSV52666323, COSV52667838, COSV52745465; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADAMTSL3 | c.107C>T p.P36L | Missense Mutation (SNP) | VAF 27/269 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV54458911; called by muse, mutect2
- ADGRG2 | c.2119G>C p.V707L (on ENST00000379869 / NM_001079858.3; = p.V704L on NM_005756.4) | Missense Mutation (SNP) | VAF 34/90 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.898); catalogued as COSV61340286; called by muse, mutect2, varscan2
- ANKRD12 | c.482C>T p.T161M | Missense Mutation (SNP) | VAF 62/181 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); catalogued as rs780779667, COSV50836171; called by muse, mutect2, varscan2
- AP4M1 | c.475A>G p.T159A | Missense Mutation (SNP) | VAF 23/97 reads (24%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.836); catalogued as COSV57997762; called by muse, mutect2, varscan2
- ARAF | c.1736G>A p.R579Q | Missense Mutation (SNP) | VAF 15/27 reads (56%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.545); catalogued as rs764281834, COSV51694149; called by muse, mutect2, varscan2
- ASMTL | c.1688A>C p.K563T | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.297); catalogued as COSV67244622; called by muse, mutect2, varscan2
- AURKAIP1 | c.499-1G>A p.X167_splice | Splice Site (SNP) | VAF 10/36 reads (28%) | catalogued as COSV57939743; called by muse, mutect2, varscan2
- CABIN1 | c.2531C>T p.S844L | Missense Mutation (SNP) | VAF 38/59 reads (64%) | SIFT deleterious (0); PolyPhen benign (0.09); catalogued as rs1315779900, COSV54085822; called by muse, mutect2, varscan2
- CD300A | c.388T>A p.S130T | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT tolerated (0.29); PolyPhen benign (0.031); catalogued as COSV60410643; called by muse, mutect2, varscan2
- CDH12 | c.941G>A p.G314E | Missense Mutation (SNP) | VAF 85/482 reads (18%) | SIFT tolerated (1); PolyPhen probably damaging (1); catalogued as rs967801376, COSV66426630; called by muse, mutect2, varscan2
- CYP2C8 | c.1054G>T p.V352L | Missense Mutation (SNP) | VAF 101/168 reads (60%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as COSV64878040; called by muse, mutect2, varscan2
- DESI2 | c.521C>G p.A174G | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (0.33); PolyPhen benign (0.106); catalogued as COSV99797991; called by muse, mutect2
- DLC1 | c.3983G>T p.C1328F (on ENST00000276297 / NM_001348081.2; = p.C891F on NM_006094.5) | Missense Mutation (SNP) | VAF 22/93 reads (24%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.803); catalogued as rs1056338432, COSV52316701; called by muse, mutect2, varscan2
- FBXO30 | c.184A>C p.N62H | Missense Mutation (SNP) | VAF 57/150 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52791880; called by muse, mutect2, varscan2
- FOXP2 | c.113G>A p.G38D | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.987); catalogued as rs760842249, COSV63490235; called by muse, mutect2, varscan2
- GHR | c.381C>G p.I127M | Missense Mutation (SNP) | VAF 74/388 reads (19%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.997); catalogued as COSV50121441; called by muse, mutect2, varscan2
- HEATR1 | c.3229G>T p.E1077* | Nonsense Mutation (SNP) | VAF 37/125 reads (30%) | catalogued as COSV63982242; called by muse, mutect2, varscan2
- HIVEP3 | c.3149C>T p.S1050F | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56019450; called by muse, mutect2, varscan2
- INPP5D | c.345C>A p.D115E | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT tolerated (0.58); PolyPhen benign (0.001); catalogued as COSV64038751; called by muse, mutect2, varscan2
- JCAD | c.1931G>A p.R644K | Missense Mutation (SNP) | VAF 83/290 reads (29%) | SIFT tolerated (0.48); PolyPhen benign (0.009); catalogued as COSV64760820; called by muse, mutect2, varscan2
- KDM3A | c.2486G>A p.S829N | Missense Mutation (SNP) | VAF 42/133 reads (32%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.468); catalogued as COSV57223807; called by muse, mutect2, varscan2
- KIAA1109 | c.791G>T p.S264I | Missense Mutation (SNP) | VAF 56/80 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV52683911; called by muse, mutect2, varscan2
- MAP3K11 | c.2543G>C p.*848Sext*119 | Nonstop Mutation (SNP) | VAF 6/9 reads (67%) | catalogued as COSV58420901; called by muse, mutect2, varscan2
- MOB1B | c.341A>G p.Y114C | Missense Mutation (SNP) | VAF 118/236 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1286249802, COSV58674577; called by muse, mutect2, varscan2
- OR2F2 | c.771C>G p.F257L | Missense Mutation (SNP) | VAF 10/164 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.869); catalogued as COSV101283798; called by muse, mutect2
- OR4C16 | c.218C>A p.T73N | Missense Mutation (SNP) | VAF 27/255 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as COSV58943214; called by mutect2, varscan2
- PCDHB11 | c.2084C>A p.A695D | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.933); catalogued as COSV61313078; called by muse, varscan2
- PDE3A | c.2786G>A p.G929E | Missense Mutation (SNP) | VAF 99/266 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62978200; called by muse, mutect2, varscan2
- PDZRN3 | c.2833G>A p.E945K | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV55208943; called by muse, mutect2, varscan2
- POLR2F | c.206G>A p.R69Q | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs763720250, COSV68091809; called by muse, mutect2, varscan2
- PPFIA2 | c.2972C>T p.A991V | Missense Mutation (SNP) | VAF 93/245 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.01); catalogued as COSV61043842; called by muse, mutect2, varscan2
- PPFIA2 | c.88C>A p.H30N | Missense Mutation (SNP) | VAF 34/90 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.08); catalogued as COSV61043853; called by muse, mutect2, varscan2
- PPP6R1 | c.1597G>T p.D533Y | Missense Mutation (SNP) | VAF 11/182 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV101336952; called by muse, mutect2
- RYR3 | c.7363C>T p.R2455C (on ENST00000389232; = p.R2456C on NM_001036.6) | Missense Mutation (SNP) | VAF 27/86 reads (31%) | SIFT tolerated (0.18); PolyPhen benign (0.036); catalogued as rs770600412, COSV66801408; called by muse, mutect2, varscan2
- SERPINB12 | c.825A>T p.K275N | Missense Mutation (SNP) | VAF 15/152 reads (10%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as COSV54034240; called by muse, mutect2, varscan2
- SSH2 | c.2371G>C p.E791Q | Missense Mutation (SNP) | VAF 97/386 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.922); catalogued as COSV52168328, COSV52174439; called by muse, mutect2, varscan2
- TBKBP1 | c.161G>A p.R54Q | Missense Mutation (SNP) | VAF 7/11 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV64654129; called by muse, mutect2, varscan2
- TGFBR3 | c.2429C>A p.S810Y | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV53028750; called by muse, mutect2, varscan2
- TTN | c.37827G>C p.L12609F (on ENST00000591111; = p.L5185F on NM_003319.4) | Missense Mutation (SNP) | VAF 43/122 reads (35%) | PolyPhen possibly damaging (0.758); catalogued as COSV60207190; called by muse, mutect2, varscan2
- UBA7 | c.1699A>C p.T567P | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.708); catalogued as COSV61092943; called by muse, mutect2, varscan2
- VIRMA | c.766G>A p.D256N | Missense Mutation (SNP) | VAF 326/1079 reads (30%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.047); catalogued as COSV52588458; called by muse, mutect2, varscan2
- ZNF583 | c.154C>T p.P52S | Missense Mutation (SNP) | VAF 183/635 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.388); catalogued as COSV52403743; called by muse, mutect2, varscan2
- C9 | c.1481del p.L494Wfs*14 | Frame Shift Del (DEL) | VAF 70/465 reads (15%) | called by mutect2, pindel, varscan2
- CHML | c.1570_1611del p.S524_E537del | In Frame Del (DEL) | VAF 14/120 reads (12%) | called by mutect2, pindel
- ECPAS | c.1893G>T p.G631= | Silent (SNP) | VAF 30/85 reads (35%) | catalogued as COSV52203160; called by muse, mutect2, varscan2
- H2BC7 | c.213C>T p.F71= | Silent (SNP) | VAF 12/111 reads (11%) | catalogued as rs149014137, COSV61912189; called by muse, mutect2, varscan2
- IGF2R | c.5268C>T p.F1756= | Silent (SNP) | VAF 36/113 reads (32%) | catalogued as rs1457464853, COSV63631084; called by muse, mutect2, varscan2
- LRRC34 | c.474C>A p.L158= | Silent (SNP) | VAF 53/158 reads (34%) | catalogued as COSV100336280, COSV57187167; called by muse, mutect2, varscan2
- MPDZ | c.1962A>G p.T654= | Silent (SNP) | VAF 121/202 reads (60%) | catalogued as COSV59948618; called by muse, mutect2, varscan2
- PRAMEF14 | c.418A>C p.R140= | Silent (SNP) | VAF 47/158 reads (30%) | called by muse, mutect2, varscan2
- PUM2 | c.2598C>T p.F866= | Silent (SNP) | VAF 69/223 reads (31%) | catalogued as COSV57583695; called by muse, mutect2, varscan2
- THSD1 | c.655C>T p.L219= | Silent (SNP) | VAF 4/37 reads (11%) | catalogued as COSV51630252; called by muse, mutect2, varscan2
